Gene-level copy-number profile of tumor specimen TCGA-38-4630-01A from TCGA case TCGA-38-4630, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 75.7 years (27,667 days).
Specimen TCGA-38-4630-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.6ab7dce7-f54d-4f9e-b232-7f094e8bf05d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-38-4630-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c909dde-7a81-4ec9-a590-15880a5e6344

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 15,897; copy number 2: 33,847; copy number 3: 7,806; copy number 4: 1,691; copy number 5: 287; copy number 6: 72; copy number 7: 22; copy number 8: 66; copy number 9: 2; copy number 10: 17; copy number 19: 6; copy number 21: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-38-4630-01): tumor purity 0.79, ploidy 1.99, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:20,037,560–20,037,972, 1 gene: AC098862.1.
- chr5:93,621,683–93,801,320, 5 genes (within-gene range 0–1): AC106818.2, NPM1P27, POU5F2, AC108102.1, AC099501.1.
- chr5:94,567,461–94,739,436, 6 genes: MTND5P12, MTND6P3, MTCYBP35, AC093311.1, AC025766.1, SLF1.
- chr5:94,788,789–94,877,777, 3 genes: AC008534.1, RPL7P18, AC008534.2.
- chr5:102,302,504–102,617,589, 4 genes (within-gene range 0–1): RN7SKP68, SLCO6A1, AC094108.1, LINC00492.
- chr5:129,397,062–129,397,147, 1 gene: MIR4460.
- chr5:163,039,291–163,039,599, 1 gene: MRPL57P6.
- chr7:5,306,790–5,563,902, 12 genes (within-gene range 0–1): TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1.
- chr7:110,590,082–110,592,204, 1 gene: AC073326.2.
- chr7:146,208,665–147,378,121, 6 genes: AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4.
- chr10:59,788,747–59,960,913, 2 genes (within-gene range 0–2): CCDC6, LINC01553.
- chr10:87,751,512–88,584,530, 11 genes: ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.
- chr14:44,860,316–45,042,322, 7 genes (within-gene range 0–3): DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28.
- chr15:43,826,980–44,195,271, 5 genes (within-gene range 0–1): WDR76, Y_RNA, FRMD5, PIN4P1, ACTBP7.
- chr15:56,029,684–56,245,082, 4 genes: RN7SL568P, CD24P2, RFX7, AC084783.1.
- chr15:56,248,787–56,249,127, 1 gene: AC068726.1.
- chr18:3,466,250–3,478,978, 1 gene: GAPLINC.
- chr20:14,522,081–14,636,524, 3 genes (within-gene range 0–2): AL121582.1, RNF11P2, MACROD2-IT1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 473 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:201,283,452–201,429,866, 6 genes, copy number 5: PKP1, TNNT2, AC119427.2, LAD1, AC119427.1, TNNI1.
- chr2:15,591,178–15,950,981, 11 genes, copy number 5 (within-gene range 3–5): DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P.
- chr2:38,408,719–38,433,573, 2 genes, copy number 9: AC016995.1, LINC01883.
- chr2:113,211,421–113,278,921, 2 genes, copy number 5: PAX8-AS1, PAX8.
- chr3:13,650,696–13,746,638, 1 gene, copy number 21 (within-gene range 4–21): LINC00620.
- chr3:157,814,822–158,106,420, 4 genes, copy number 6: AC079943.2, RN7SKP46, AC079943.1, SHOX2.
- chr3:169,083,499–170,305,977, 31 genes, copy number 5 (within-gene range 4–5): MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA.
- chr3:172,425,850–172,711,218, 8 genes, copy number 8–19 (within-gene range 4–19): BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2.
- chr3:177,294,442–177,767,379, 7 genes, copy number 6 (within-gene range 4–6): LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1.
- chr4:1,692,731–1,856,156, 6 genes, copy number 6–7 (within-gene range 2–7): SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1.
- chr4:76,435,229–76,783,253, 5 genes, copy number 6 (within-gene range 2–6): SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH.
- chr6:11,414,636–11,516,466, 4 genes, copy number 5: AL445430.2, AL445430.1, RNU1-64P, THAP12P5.
- chr6:18,304,854–18,368,644, 4 genes, copy number 5: AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9.
- chr8:127,663,280–127,742,951, 3 genes, copy number 5: AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,890,720, 2 genes, copy number 5: MIR1204, AC084123.1.
- chr8:141,207,166–141,308,305, 1 gene, copy number 8 (within-gene range 3–8): SLC45A4.
- chr8:141,252,286–141,507,230, 13 genes, copy number 8 (within-gene range 2–8): AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38.
- chr11:13,668,668–13,732,346, 1 gene, copy number 5 (within-gene range 2–5): FAR1.
- chr11:13,685,499–13,924,863, 9 genes, copy number 5: RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683.
- chr11:63,797,784–64,329,504, 39 genes, copy number 5: RN7SL596P, SPINDOC, ATP5MGP1, MARK2, RNU6-1306P, RCOR2, NAA40, RNU6-45P, COX8A, AP000721.1, OTUB1, MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1, STIP1, FERMT3, TRPT1, NUDT22, AP001453.1, DNAJC4, VEGFB, FKBP2, AP001453.3, PPP1R14B, PPP1R14B-AS1, AP001453.2, PLCB3, BAD, GPR137, KCNK4, KCNK4-TEX40, Y_RNA, CATSPERZ, ESRRA, TRMT112, PRDX5, AP003774.2.
- chr14:35,362,232–35,513,089, 7 genes, copy number 5: AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6.
- chr14:67,819,779–68,730,218, 1 gene, copy number 7 (within-gene range 1–7): RAD51B.
- chr14:68,149,617–68,628,445, 6 genes, copy number 7: RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2.
- chr15:90,717,346–90,963,125, 13 genes, copy number 7 (within-gene range 3–7): BLM, SNORD18, AC124248.2, AC124248.1, RN7SL363P, FURIN, FES, MAN2A2, AC068831.3, HDDC3, UNC45A, RCCD1-AS1, RCCD1.
- chr17:39,461,486–39,864,312, 15 genes, copy number 8 (within-gene range 3–8): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr17:75,318,076–75,757,818, 20 genes, copy number 6 (within-gene range 2–6): GRB2, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4.
- chr19:29,526,499–31,417,794, 29 genes, copy number 6–10 (within-gene range 2–10): VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2.
- chr19:36,636,618–39,428,415, 129 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:45,001,449–45,974,044, 54 genes, copy number 5–8 (within-gene range 3–8): RELB, CLASRP, RNU6-611P, ZNF296, GEMIN7-AS1, GEMIN7, MARK4, PPP1R37, EIF5AP3, AC005757.1, NKPD1, TRAPPC6A, BLOC1S3, EXOC3L2, CKM, RPS16P9, KLC3, ERCC2, PPP1R13L, POLR1G, ERCC1, MIR6088, FOSB, RTN2, PPM1N, VASP, OPA3, GPR4, EML2, MIR330, EML2-AS1, RN7SL836P, GIPR, MIR642A, MIR642B, SNRPD2, QPCTL, FBXO46, AC007191.1, BHMG1, SIX5, AC074212.1, DM1-AS, DMPK, AC011530.1, DMWD, RSPH6A, SYMPK, AC092301.1, FOXA3, IRF2BP1, MYPOP, NANOS2, NOVA2.
- chr20:31,514,410–31,723,989, 13 genes, copy number 6: HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.
- chr20:47,209,214–47,412,327, 5 genes, copy number 5 (within-gene range 2–5): ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754.
- chr20:50,118,254–50,283,250, 7 genes, copy number 6 (within-gene range 3–6): PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON.
- chr20:62,143,769–62,447,677, 15 genes, copy number 5 (within-gene range 2–5): SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1.

Autosomal genes at a single copy (total copy number 1): 13,548. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
